Somatic mutation profile of tumor specimen ALCH-B4XB-TTP1-A (aliquot ALCH-B4XB-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4XB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,785 days).
Specimen ALCH-B4XB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b4c4fe4-bc26-4a16-930b-5127d4868d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XB-NB1-A (Blood Derived Normal), aliquot ALCH-B4XB-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6be08560-f74a-4ac6-85b3-fe95a73a9d66

The open-access MAF lists 110 somatic variants for this specimen: 67 protein-altering or splice-affecting, 28 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 28, Nonsense Mutation 8, Intron 6, 5'UTR 3, 3'Flank 2, RNA 2, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 276/974 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CNGA1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 29/166 reads (17%) | catalogued as rs369717052, CM1511726, COSV62057121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 187/960 reads (19%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- STK11 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 33/174 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520017, COSV58821219; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 126/400 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 44/838 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- BAZ1A | c.1804A>G p.S602G | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs747648725; called by muse, mutect2, varscan2
- BCORL1 | c.4764C>A p.D1588E | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV54406017; called by muse, mutect2, varscan2
- BRS3 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV101036567; called by muse, mutect2, varscan2
- CCKBR | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs145313566; called by muse, mutect2, varscan2
- CFAP54 | c.5605G>A p.V1869M | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776062493; called by muse, mutect2, varscan2
- CORO2B | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274829318, COSV55950034; called by muse, mutect2, varscan2
- DEPTOR | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as rs546279612; called by muse, mutect2, varscan2
- ERV3-1 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs201764711; called by muse, mutect2, varscan2
- KLHL40 | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55135175; called by muse, mutect2, varscan2
- MCC | c.2390T>C p.M797T | Missense Mutation (SNP) | VAF 146/712 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs549434303; called by muse, mutect2, varscan2
- MCC | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 179/623 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs770380947; called by muse, mutect2, varscan2
- MDN1 | c.13582G>A p.E4528K | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65524608; called by muse, mutect2
- MGLL | c.71A>G p.N24S (on ENST00000398104 / NM_001003794.2; = p.N34S on NM_007283.6) | Missense Mutation (SNP) | VAF 191/804 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs771477969, COSV99411565, COSV99412205; called by muse, mutect2, varscan2
- MRGPRF | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs1227879038, COSV57995725; called by muse, mutect2, varscan2
- NAA60 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1309325172; called by muse, mutect2, varscan2
- PPP1R36 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV53903647; called by muse, mutect2
- RB1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as CM040260, COSV57297810; called by muse, mutect2, varscan2
- SCRT2 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as rs749402209, COSV99072357; called by muse, mutect2, varscan2
- SIGLEC12 | c.1338C>A p.C446* (on ENST00000291707 / NM_053003.4; = p.C328* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 141/535 reads (26%) | catalogued as COSV52464618; called by muse, mutect2, varscan2
- STIM1 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 12/333 reads (4%) | catalogued as COSV100330922, COSV100331132, COSV56154202; called by muse, mutect2
- TBX5 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 101/573 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1244291083; called by muse, mutect2, varscan2
- TDRD15 | c.4011G>C p.E1337D | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.343); catalogued as COSV68267022; called by muse, mutect2, varscan2
- TTBK2 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 96/601 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51160979; called by muse, mutect2, varscan2
- UTRN | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 72/537 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62348882; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 24/430 reads (6%) | catalogued as COSV58744891; called by muse, mutect2
- ABCA13 | c.15139T>A p.S5047T | Missense Mutation (SNP) | VAF 278/1085 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- AIFM1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 216/711 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD13C | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 65/319 reads (20%) | called by muse, mutect2, varscan2
- BAZ2B | c.6265G>C p.V2089L | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNKSR2 | c.2702G>C p.R901T | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- COQ8B | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by mutect2, varscan2
- DEPDC1 | c.228G>C p.L76F | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DEPDC1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.487); called by muse, varscan2
- DLGAP1 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- DYNC2H1 | c.3925C>T p.L1309F | Missense Mutation (SNP) | VAF 72/458 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBRSL1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GAK | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPHA2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 46/1062 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- GTF3C1 | c.5110T>G p.C1704G | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- HOMER3 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); called by muse, mutect2
- IL1RAPL2 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IPO13 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRC37B | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 127/439 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MED14 | c.3854T>C p.F1285S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MTPAP | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 118/358 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO15B | c.7147_7150del p.E2383Tfs*36 | Frame Shift Del (DEL) | VAF 114/575 reads (20%) | called by mutect2, pindel, varscan2
- NEK10 | c.2092C>A p.P698T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OBSCN | c.14287G>C p.E4763Q | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2T11 | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 82/475 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PTPRK | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 86/793 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOC | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- RTL4 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 36/491 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2
- S1PR5 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 155/476 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SCN1A | c.5049C>G p.I1683M (on ENST00000303395 / NM_001202435.3; = p.I1672M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORBS2 | c.3095C>G p.P1032R (on ENST00000284776 / NM_021069.5; = p.P598R on NM_003603.6) | Missense Mutation (SNP) | VAF 118/472 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TNFAIP6 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- USH1C | c.1596G>A p.W532* | Nonsense Mutation (SNP) | VAF 74/400 reads (19%) | called by muse, mutect2, varscan2
- UVRAG | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H14 | c.1047A>C p.Q349H | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZFHX4 | c.4129C>T p.Q1377* | Nonsense Mutation (SNP) | VAF 63/445 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1503C>T p.N501= | Silent (SNP) | VAF 135/613 reads (22%) | catalogued as rs144042848; called by muse, mutect2, varscan2
- BTBD10 | c.744G>A p.L248= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV53399502; called by muse, mutect2
- CASS4 | c.669G>A p.V223= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1284687254, COSV64386038; called by muse, mutect2, varscan2
- CATSPER4 | c.870C>T p.F290= | Silent (SNP) | VAF 32/327 reads (10%) | called by muse, mutect2, varscan2
- CYBA | c.276C>T p.V92= | Silent (SNP) | VAF 52/662 reads (8%) | catalogued as rs1262515513; called by muse, mutect2
- DLG5 | c.2049C>T p.L683= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- DNAH10 | c.1278C>T p.P426= (on ENST00000409039; = p.P365= on NM_207437.3) | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as rs979868924, COSV68990971; called by muse, mutect2, varscan2
- DYNLL1 | c.186C>T p.F62= | Silent (SNP) | VAF 58/435 reads (13%) | catalogued as rs780634489, COSV99655538; called by muse, mutect2, varscan2
- FAT2 | c.8121G>T p.G2707= | Silent (SNP) | VAF 73/271 reads (27%) | called by muse, mutect2, varscan2
- GLI1 | c.1005C>T p.H335= | Silent (SNP) | VAF 46/283 reads (16%) | catalogued as rs141854128; called by muse, varscan2
- GPRIN1 | c.255C>T p.D85= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1256358821, COSV56138706, COSV56139429; called by muse, mutect2, varscan2
- HK3 | c.2463C>T p.D821= | Silent (SNP) | VAF 37/368 reads (10%) | catalogued as rs200491262, COSV99457540; called by muse, mutect2, varscan2
- MYO1B | c.1182C>T p.F394= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as rs1437595675, COSV58430850, COSV58434427, COSV58437963; called by muse, mutect2, varscan2
- NAT16 | c.156A>T p.P52= | Silent (SNP) | VAF 155/566 reads (27%) | called by muse, mutect2, varscan2
- OIT3 | c.1344G>A p.L448= | Silent (SNP) | VAF 14/75 reads (19%) | called by mutect2, varscan2
- POLA1 | c.4380G>A p.V1460= | Silent (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- RAB1A | c.558G>A p.E186= | Silent (SNP) | VAF 30/447 reads (7%) | catalogued as rs1424805911; called by muse, mutect2
- SCN1A | c.5202C>G p.L1734= (on ENST00000303395 / NM_001202435.3; = p.L1723= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/641 reads (7%) | called by muse, mutect2
- SMC1B | c.2634C>G p.V878= | Silent (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- SPTBN4 | c.1167G>A p.V389= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- STRADA | c.732C>A p.L244= (on ENST00000336174 / NM_001363786.1; = p.L207= on NM_153335.6) | Silent (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- STXBP5 | c.2859G>A p.L953= (on ENST00000321680 / NM_001127715.2; = p.L917= on NM_139244.4) | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV51649639, COSV51651850; called by muse, mutect2, varscan2
- SULF1 | c.1461G>A p.Q487= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- TXNDC9 | c.399C>T p.F133= | Silent (SNP) | VAF 38/344 reads (11%) | called by muse, mutect2, varscan2
- WDR87 | c.7755C>T p.D2585= | Silent (SNP) | VAF 69/269 reads (26%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.420G>A p.K140= | Silent (SNP) | VAF 123/475 reads (26%) | called by muse, mutect2, varscan2
- ZNF541 | c.2664G>A p.L888= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as rs1056915684, COSV54547585; called by muse, varscan2
- ZNF574 | c.1119C>T p.F373= | Silent (SNP) | VAF 83/547 reads (15%) | catalogued as rs113091672, COSV55903296; called by muse, mutect2, varscan2
- ANKRD54 | c.-92C>G | 5'UTR (SNP) | VAF 14/82 reads (17%) | catalogued as rs377071473; called by mutect2, varscan2
- AP000769.3 | chr11:65503456 G>C | 5'Flank (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- ATP5F1B | c.311-97G>A | Intron (SNP) | VAF 30/222 reads (14%) | catalogued as rs760854243; called by muse, mutect2, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 16/277 reads (6%) | catalogued as rs1291738365; called by muse, mutect2
- CITED1 | c.-66+1145G>A | Intron (SNP) | VAF 55/439 reads (13%) | catalogued as rs1335109931; called by muse, mutect2, varscan2
- COL11A2 | c.-27G>A | 5'UTR (SNP) | VAF 132/762 reads (17%) | called by muse, mutect2, varscan2
- DEPDC1 | c.-9G>A | 5'UTR (SNP) | VAF 42/229 reads (18%) | catalogued as COSV100920208; called by muse, varscan2
- EML2 | c.1122+117C>G | Intron (SNP) | VAF 36/566 reads (6%) | called by muse, mutect2
- FSCN2 | c.*6C>T | 3'UTR (SNP) | VAF 67/232 reads (29%) | catalogued as rs939200436; called by muse, mutect2, varscan2
- HSF4 | c.1325-39G>A | Intron (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- LINGO1-AS1 | n.274T>C | RNA (SNP) | VAF 29/250 reads (12%) | called by muse, mutect2, varscan2
- OTOA | chr16:21760551 C>T | 3'Flank (SNP) | VAF 42/660 reads (6%) | catalogued as rs751703522, COSV99625890; called by muse, mutect2
- SNORD115-1 | n.36G>A | RNA (SNP) | VAF 106/691 reads (15%) | called by muse, mutect2, varscan2
- TPM3 | c.567-140C>G | Intron (SNP) | VAF 46/730 reads (6%) | called by muse, mutect2
- WDR17 | chr4:176181525 A>C | 3'Flank (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
